CCDI case PBCUJB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/5e94b4d0-e272-4711-af7c-868bab66c1a2

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0DZRY6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZRYI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DZRZ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
